Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-6032, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-6032-01A (Primary Tumor).

Department of Pathology

Tissue Source Site (TSS) #: [REDACTED]

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA (7.0 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE
(95% CLEAR CELLS,
5% EOSINOPHILIC CELLS), FUHRMAN NUCLEAR GRADE 3, CONFINED TO
THE KIDNEY.

(SEE COMMENT)

Margins of resection free of tumor.

COMMENT

The renal cell carcinoma in the right kidney does not invade into the perinephric adipose tissue, renal sinus adipose tissue, or the renal vein.

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A radical nephrectomy specimen, which includes the perinephric fat (21.0 x 10.0 x 6.0 cm) and kidney (12.0 x 5.0 x 4.3 cm).

Located within the inferior and mid pole of the kidney is a well-circumscribed nodular tumor (7.0 x 6.0 x 5.5 cm). The cut surface of the tumor is tan-yellow, soft admixed with foci of hyalinized tissue. The tumor bulges into the perinephric fat without invading into it. The tumor pushes close to the renal sinus fat and renal pelvis without invading into either structure. The renal vein is also free of tumor. The non-neoplastic renal parenchyma is unremarkable. The ureter (5.0 cm in length and 0.3 cm in circumference) and the renal vein (less than 1.0 cm in length and 0.6 cm in diameter) are unremarkable. No adrenal gland is identified.

INK CODE: Blue - perinephric fat closest to the tumor.

SECTION CODE: A1, renal vein and ureteral margin; A2, tumor, close to renal pelvis; A3-A4, tumor with renal sinus fat; A5, A6 tumor in relation to the perinephric fat; A7-A9, tumor in relation to the normal parenchyma; A10-A12, tumor; A13, normal kidney parenchyma.

A representative portion of the tumor is submitted for the vaccine protocol. A representative portion of the tumor is also submitted for possible EM studies. [REDACTED]

CLINICAL HISTORY

Mass of right kidney.

SNOMED CODES

T-71000, M-83123

Source: NCI Genomic Data Commons file 1328d815-64af-43db-a6a4-667487c3dd6f (TCGA-CJ-6032.F92C3798-9A25-4EDA-94B7-6F59C7994AE2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).